Somatic mutation profile of tumor specimen C3N-01088-04 (aliquot CPT0212590006) from CPTAC case C3N-01088, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-01088-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36518079-96b8-4514-a0a8-ea6dd16675b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01088-71 (Blood Derived Normal), aliquot CPT0212680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63327762-fd4a-4c3a-a2f2-449af92c3eab

The open-access MAF lists 110 somatic variants for this specimen: 78 protein-altering or splice-affecting, 22 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 22, Frame Shift Del 9, Intron 5, Splice Site 3, Nonsense Mutation 3, 5'UTR 3, RNA 2, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.7075G>A p.D2359N | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs1484887578, COSV99268227; called by muse, mutect2, varscan2
- ARHGEF39 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761690775, COSV58396631; called by muse, mutect2, varscan2
- CCDC197 | c.438del p.K146Nfs*30 | Frame Shift Del (DEL) | VAF 48/231 reads (21%) | catalogued as COSV100113648; called by mutect2, pindel, varscan2
- EFHB | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV55555924; called by muse, mutect2, varscan2
- ENDOD1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1431727685, COSV99566713; called by muse, mutect2, varscan2
- ERBIN | c.2521A>G p.S841G | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1353309271; called by muse, mutect2, varscan2
- HAPLN3 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.413); catalogued as rs756999566, COSV61363677; called by muse, mutect2
- HCK | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 110/404 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746647795; called by muse, mutect2, varscan2
- IGSF10 | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.171); catalogued as rs1191618679; called by muse, mutect2
- METTL3 | c.1135C>A p.R379S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771889155, COSV99398042; called by muse, varscan2
- MOV10 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs201257888; called by muse, mutect2, varscan2
- NALCN | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.321); catalogued as rs1255554276, COSV51920828; called by muse, mutect2
- OTX1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56996195; called by muse, varscan2
- PBRM1 | c.528+1G>C p.X176_splice | Splice Site (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56275199, COSV56280015; called by muse, mutect2
- PSMA7 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53379126; called by muse, mutect2, varscan2
- RP1L1 | c.2675C>T p.T892I | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.181); catalogued as rs763307651; called by muse, mutect2, varscan2
- TENM1 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 77/300 reads (26%) | catalogued as COSV64442938; called by muse, mutect2, varscan2
- TEX11 | c.133G>A p.A45T (on ENST00000344304; = p.A30T on NM_031276.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs904176751; called by muse, mutect2, varscan2
- VHL | c.203C>G p.S68W | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM003058, CM971566, COSV56542559, COSV56566398; called by muse, varscan2
- VHL | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 121/318 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.644); catalogued as rs1428175816, COSV56570239, COSV56572326; ClinVar: uncertain significance; called by muse, varscan2
- ADAMTS15 | c.1390T>C p.Y464H | Missense Mutation (SNP) | VAF 56/327 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ADGRA3 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- APAF1 | c.2347G>T p.V783L (on ENST00000551964 / NM_181861.2; = p.V772L on NM_001160.3) | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- APOL4 | c.338C>G p.P113R (on ENST00000352371 / NM_145660.2; = p.P110R on NM_030643.4) | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AREG | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 61/387 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- BIRC6 | c.4208A>G p.K1403R | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- BRD8 | c.116+1G>A p.X39_splice | Splice Site (SNP) | VAF 55/218 reads (25%) | called by muse, mutect2, varscan2
- CCDC175 | c.573del p.T192Lfs*4 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | called by mutect2, pindel, varscan2
- CCDC65 | c.910del p.L304Cfs*19 | Frame Shift Del (DEL) | VAF 73/347 reads (21%) | called by mutect2, pindel, varscan2
- CDC5L | c.1705C>G p.Q569E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2
- CDK14 | c.407_439del p.E136_Y146del (on ENST00000380050 / NM_001287135.2; = p.E118_Y128del on NM_012395.3) | In Frame Del (DEL) | VAF 12/88 reads (14%) | called by mutect2, pindel
- CELF4 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP120 | c.2496A>C p.R832S | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- CLDN34 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COCH | c.577del p.S193Vfs*22 (on ENST00000216361 / NM_001347720.1; = p.S128Vfs*22 on NM_004086.3) | Frame Shift Del (DEL) | VAF 106/337 reads (31%) | called by mutect2, pindel, varscan2
- DCHS1 | c.3196G>T p.E1066* | Nonsense Mutation (SNP) | VAF 24/269 reads (9%) | called by muse, mutect2
- DENND5A | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLC1 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DYNLRB1 | c.78A>T p.E26D | Missense Mutation (SNP) | VAF 78/261 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EIF5 | c.1252A>G p.K418E | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ERGIC1 | c.766-2A>G p.X256_splice | Splice Site (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- GTF2I | c.1166T>A p.L389H (on ENST00000573035 / NM_032999.4; = p.L348H on NM_001518.5) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HERC5 | c.551_552insA p.V185Cfs*35 | Frame Shift Ins (INS) | VAF 122/558 reads (22%) | called by mutect2, pindel, varscan2
- KCNU1 | c.2812C>A p.H938N | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.198); called by muse, mutect2
- KDM5C | c.838del p.D280Mfs*2 | Frame Shift Del (DEL) | VAF 74/481 reads (15%) | called by mutect2, pindel, varscan2
- KLHL40 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KRT76 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.157); called by muse, mutect2
- KRTAP29-1 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- MAP3K7 | c.755T>A p.I252K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- MYO15B | c.8981C>T p.P2994L | Missense Mutation (SNP) | VAF 177/607 reads (29%) | PolyPhen benign (0.364); called by muse, mutect2, varscan2
- NIPBL | c.8207G>C p.S2736T | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.154); called by muse, mutect2
- NKAP | c.143C>G p.S48C | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- NOX1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- OR5AC2 | c.248T>A p.M83K | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PCDH9 | c.3677G>A p.G1226E (on ENST00000377865 / NM_203487.3; = p.G1192E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- PCDHAC1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLCXD2 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 92/332 reads (28%) | called by muse, mutect2, varscan2
- PLIN3 | c.1217A>C p.E406A | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PSMB4 | c.211_221del p.M71Lfs*30 | Frame Shift Del (DEL) | VAF 67/317 reads (21%) | called by mutect2, pindel, varscan2
- RGS19 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SAGE1 | c.274G>T p.V92L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SCIN | c.868G>C p.A290P (on ENST00000297029 / NM_001112706.3; = p.A43P on NM_033128.3) | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SCN3A | c.1227C>G p.F409L | Missense Mutation (SNP) | VAF 111/381 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCRIB | c.4457C>T p.S1486F | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC24A | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A3 | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLF2 | c.2896A>C p.I966L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, varscan2
- SMTN | c.1319_1322del p.P440Lfs*17 | Frame Shift Del (DEL) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- SRD5A1 | c.412del p.C138Vfs*9 | Frame Shift Del (DEL) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D1 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TFDP2 | c.490A>C p.N164H (on ENST00000489671 / NM_001178139.2; = p.N103H on NM_006286.5) | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TINAGL1 | c.1093+6C>T | Splice Region (SNP) | VAF 19/101 reads (19%) | called by muse, mutect2, varscan2
- TRAV13-1 | c.117dup p.I40Yfs*17 | Frame Shift Ins (INS) | VAF 18/122 reads (15%) | called by mutect2, pindel
- TRIM40 | c.707del p.L236* (on ENST00000376724; = p.L207* on NM_138700.4) | Frame Shift Del (DEL) | VAF 63/208 reads (30%) | called by mutect2, pindel, varscan2
- TUFT1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 56/205 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBE2E3 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- UNC80 | c.7768G>T p.D2590Y | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VSTM2A | c.529T>G p.S177A | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AJAP1 | c.513C>T p.G171= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- BAP1 | c.1008G>A p.V336= | Silent (SNP) | VAF 9/182 reads (5%) | called by muse, mutect2
- BOD1L1 | c.5382G>A p.T1794= | Silent (SNP) | VAF 73/214 reads (34%) | catalogued as rs771170062; called by muse, mutect2, varscan2
- BTBD8 | c.1026T>C p.I342= | Silent (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- CFAP54 | c.4908T>G p.L1636= | Silent (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- CREBBP | c.7023C>T p.N2341= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1395407807, COSV52122263; called by muse, mutect2, varscan2
- CSMD3 | c.9891T>C p.P3297= (on ENST00000297405 / NM_001363185.1; = p.P3128= on NM_052900.3) | Silent (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- D2HGDH | c.1482C>T p.A494= | Silent (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- DSC1 | c.186C>A p.I62= | Silent (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- EDEM2 | c.51T>G p.P17= | Silent (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- LRP1 | c.5064G>C p.R1688= | Silent (SNP) | VAF 65/216 reads (30%) | called by muse, mutect2, varscan2
- MEIS1 | c.897C>T p.Y299= | Silent (SNP) | VAF 59/227 reads (26%) | catalogued as rs754471341; called by muse, mutect2, varscan2
- OLIG2 | c.297G>A p.K99= | Silent (SNP) | VAF 158/456 reads (35%) | called by muse, mutect2, varscan2
- PNCK | c.111C>T p.S37= (on ENST00000340888 / NM_001366975.1; = p.S120= on NM_001039582.3) | Silent (SNP) | VAF 71/263 reads (27%) | catalogued as rs782574746; called by muse, mutect2, varscan2
- QPCT | c.411C>A p.L137= | Silent (SNP) | VAF 109/649 reads (17%) | catalogued as COSV58120046; called by muse, mutect2, varscan2
- SIL1 | c.756T>A p.A252= | Silent (SNP) | VAF 337/804 reads (42%) | called by muse, mutect2, varscan2
- SLC4A2 | c.624T>C p.S208= | Silent (SNP) | VAF 28/88 reads (32%) | called by muse, varscan2
- TNXB | c.8961G>A p.G2987= (on ENST00000647633; = p.G2740= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/249 reads (28%) | catalogued as rs1369839006; called by muse, mutect2, varscan2
- XPO1 | c.1716C>T p.F572= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs747204172, COSV68944638; called by muse, mutect2, varscan2
- ZNF366 | c.1116C>T p.L372= | Silent (SNP) | VAF 39/260 reads (15%) | catalogued as rs752354224, COSV59215790; called by muse, mutect2, varscan2
- ZNF544 | c.1683T>G p.S561= | Silent (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- ZWILCH | c.21C>T p.C7= | Silent (SNP) | VAF 60/230 reads (26%) | catalogued as rs770824598; called by muse, mutect2, varscan2
- AC002511.3 | n.325-68G>T | Intron (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2
- AL391261.1 | n.277G>T | RNA (SNP) | VAF 28/205 reads (14%) | called by muse, mutect2, varscan2
- MRPL13 | c.27+9G>A | Intron (SNP) | VAF 53/349 reads (15%) | catalogued as COSV100012287; called by muse, mutect2, varscan2
- PPP2R5C | c.93+2185G>A | Intron (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- PRPF6 | c.-26T>A | 5'UTR (SNP) | VAF 89/360 reads (25%) | called by muse, mutect2, varscan2
- RGS12 | c.1882-436A>G | Intron (SNP) | VAF 29/87 reads (33%) | called by muse, mutect2, varscan2
- SLC11A2 | c.49+1813A>G | Intron (SNP) | VAF 30/143 reads (21%) | called by muse, mutect2, varscan2
- TMPRSS11BNL | n.163A>C | RNA (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- UCHL1 | c.-10C>T | 5'UTR (SNP) | VAF 100/543 reads (18%) | called by muse, mutect2, varscan2
- ZNF224 | c.-36T>C | 5'UTR (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
